Somatic mutation profile of tumor specimen MP2PRT-PARDEY-TMP1-A (aliquot MP2PRT-PARDEY-TMP1-A-1-0-D-A83N-36) from MP2PRT case MP2PRT-PARDEY, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.6 years (2,059 days).
Specimen MP2PRT-PARDEY-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9b13f4b2-f6e1-4d6c-be8b-b2edb26d91f8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARDEY-NM1-A (Blood Derived Cancer - Bone Marrow, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARDEY-NM1-A-1-0-D-A83N-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/74078f67-bc61-4368-b736-5ab06fbf58df

The open-access MAF lists 37 somatic variants for this specimen: 25 protein-altering or splice-affecting, 10 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, Silent 10, In Frame Del 1, Intron 1, Frame Shift Del 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACADL | c.104G>A p.R35H | Missense Mutation (SNP) | VAF 35/84 reads (42%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.999); catalogued as rs763970340; called by muse, mutect2, varscan2
- AKAP8L | c.1789C>T p.P597S | Missense Mutation (SNP) | VAF 324/790 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs972739020; called by muse, varscan2
- BSN | c.3940C>T p.P1314S | Missense Mutation (SNP) | VAF 228/553 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56530133; called by muse, mutect2, varscan2
- C1orf94 | c.79G>A p.G27R | Missense Mutation (SNP) | VAF 210/526 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.608); catalogued as rs1445868579; called by muse, mutect2, varscan2
- EIF5A2 | c.423G>A p.M141I | Missense Mutation (SNP) | VAF 10/202 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.019); catalogued as COSV55543058; called by muse, mutect2
- FSIP2 | c.1139A>T p.N380I | Missense Mutation (SNP) | VAF 48/125 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as COSV58081795; called by muse, mutect2
- GRM7 | c.760G>A p.V254M | Missense Mutation (SNP) | VAF 68/173 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.141); catalogued as rs368787807, COSV63139542; called by muse, mutect2, varscan2
- HCN1 | c.819G>T p.R273S | Missense Mutation (SNP) | VAF 77/153 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.561); catalogued as COSV57497745; called by muse, mutect2, varscan2
- MUC5AC | c.835G>A p.V279M | Missense Mutation (SNP) | VAF 209/472 reads (44%) | SIFT tolerated (0.12); catalogued as rs747675063; called by muse, mutect2, varscan2
- OTOR | c.102T>G p.D34E | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs534633227; called by muse, mutect2, varscan2
- PGK2 | c.1072G>A p.E358K | Missense Mutation (SNP) | VAF 105/232 reads (45%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as rs865897397, COSV100505383, COSV59163146; called by muse, mutect2, varscan2
- TTLL9 | c.830G>A p.R277H | Missense Mutation (SNP) | VAF 148/370 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs373712171; called by muse, mutect2
- ADGRD2 | c.2020G>A p.E674K | Missense Mutation (SNP) | VAF 113/306 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.149); called by muse, mutect2, varscan2
- AKAP8L | c.1790C>T p.P597L | Missense Mutation (SNP) | VAF 323/787 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.01); called by muse, varscan2
- DNAH12 | c.4405G>A p.D1469N (on ENST00000351747; = p.D1492N on NM_001366028.2) | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- FLG | c.12092A>T p.Y4031F | Missense Mutation (SNP) | VAF 79/185 reads (43%) | SIFT tolerated (0.38); PolyPhen benign (0.177); called by muse, mutect2, varscan2
- GLDN | c.55G>A p.A19T | Missense Mutation (SNP) | VAF 184/663 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.151); called by muse, mutect2, varscan2
- IGHV1-69 | c.349_351delinsCT p.R117del | Frame Shift Del (DEL) | VAF 22/32 reads (69%) | called by pindel, varscan2*
- LRP4 | c.3026A>T p.E1009V | Missense Mutation (SNP) | VAF 103/270 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- PCDHGA7 | c.2252A>G p.Q751R | Missense Mutation (SNP) | VAF 160/419 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- RNF224 | c.218G>C p.S73T | Missense Mutation (SNP) | VAF 252/671 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- SAMD4A | c.267G>T p.L89F | Missense Mutation (SNP) | VAF 113/242 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- UBE2J2 | c.566_577del p.V189_D192del | In Frame Del (DEL) | VAF 158/559 reads (28%) | called by mutect2, varscan2
- WRNIP1 | c.455C>G p.A152G | Missense Mutation (SNP) | VAF 36/928 reads (4%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.035); called by muse, mutect2
- ZC3H18 | c.1378C>T p.R460W | Missense Mutation (SNP) | VAF 224/612 reads (37%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); called by muse, varscan2
- CFAP61 | c.2703G>A p.A901= | Silent (SNP) | VAF 216/522 reads (41%) | catalogued as COSV55630337; called by muse, varscan2
- MKRN3 | c.258G>A p.P86= | Silent (SNP) | VAF 246/606 reads (41%) | catalogued as rs992964077, COSV100090600, COSV58809496; called by muse, mutect2, varscan2
- MRC2 | c.342G>A p.R114= | Silent (SNP) | VAF 258/599 reads (43%) | called by muse, mutect2, varscan2
- NALCN | c.4551C>T p.Y1517= | Silent (SNP) | VAF 20/403 reads (5%) | catalogued as rs748173874, COSV51929902; called by muse, mutect2
- OR5R1 | c.18C>T p.I6= | Silent (SNP) | VAF 35/104 reads (34%) | catalogued as COSV56571587; called by muse, mutect2, varscan2
- PCDH11X | c.927C>T p.I309= | Silent (SNP) | VAF 39/91 reads (43%) | called by muse, mutect2, varscan2
- PXDNL | c.2835G>A p.A945= | Silent (SNP) | VAF 236/484 reads (49%) | catalogued as rs533962228, COSV62501917; called by muse, mutect2, varscan2
- SERPINB11 | c.1095C>T p.F365= | Silent (SNP) | VAF 169/372 reads (45%) | called by muse, mutect2, varscan2
- SGCG | c.303A>T p.S101= | Silent (SNP) | VAF 73/171 reads (43%) | called by muse, mutect2, varscan2
- UHRF1BP1L | c.1914A>G p.K638= | Silent (SNP) | VAF 63/130 reads (48%) | called by muse, mutect2, varscan2
- DNAJC12 | c.297+25T>G | Intron (SNP) | VAF 102/227 reads (45%) | called by muse, mutect2, varscan2
- TBC1D3F | c.*11G>A | 3'UTR (SNP) | VAF 371/965 reads (38%) | catalogued as rs1446633332; called by muse, mutect2, varscan2
